Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NT, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NT-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old with prostate cancer. Status post radical prostatectomy. Two month history of worsening dysphagia - EGD with biopsy and chest CT revealing lower esophageal adenocarcinoma.

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus." 5.2 cm long segment of esophagus that is 3.5 cm in diameter. Attached is the distal cuff of stomach, 4.3 cm in length x 4.3 cm in width x 1.3 cm thick. The mucosa of the esophagus is prominently folded and gray-white. The gastric mucosa is a rugated tan-gray that is remarkable for a 2.3 x 1.7 x 0.2 cm ulcerative gray-pink tumor that is 2.0 cm away from the distal gastric margin. This tumor has been previously incised by the surgeon. Tumor arises within the gastric mucosa directly underlying the squamocolumnar junction. The tumor has a maximum depth of 0.8 cm and extends to the serosa into the surrounding adipose. Upon further sectioning the tumor also courses under the mucosa through the muscular wall and extends to 1.5 cm away from the distal margin of resection. Four possible lymph nodes are identified ranging from 0.3 to 1.1 cm. The largest lymph node has a gray-white surface.
- 1A. Tumor to distal gastric margin.
- 1B. Tumor to squamous columnar junction.
- 1C-D. Tumor to deep.
- 1E. Squamous columnar junction.
- 1F. Normal gastric and esophageal tissue.
- 1G. Three lymph nodes.
- 1H. Largest lymph node, bivalved.
2. "Cervical esophageal margin." Tubular portion of pink-tan esophagus, 2.2 cm in length and 1.7 cm in diameter. One margin is stapled with the opposite remaining open designated the proximal margin.
- 2A. Proximal margin.

PROCEDURE:

VERIFIED BY

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

Arising in: Barrett's mucosa.

Depth of invasion: Adventitia.

ONE ICD-O. 3
Adenocarcinoma NOS
8140/3
path
Adenocarcinoma, mucinous NOS
8480/3
Site: Esophagus, distal third
C155
JW 11/7/14

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Number of positive lymph nodes: 0.
Extranodal metastasis: Unknown.
Pattern of invasion: Infiltrative.
Esophageal and gastric resection margins involved: No.
Deep resection margin involved: Yes.
TNM classification: T3 N0 MX.

PROCEDURE:

VERIFIED BY:

1. Esophagus and proximal stomach, resection: Transmurally invasive adenocarcinoma with mucinous features. Tumor extends to deep margin of excision. Four lymph nodes negative for neoplasm. Short segment Barrett's esophagus. Proximal and distal margins free of neoplasm. Please see template. *Purple review of top slide - 0% mucinous.*
2. Cervical esophagus, excision: No Barrett's or carcinoma identified.

M.D.

I, M.D., the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 51e78144-d584-4ac5-9ebd-44f0f11a156a (TCGA-L5-A8NT.8D353E8D-4832-47B9-9E81-677CDF18DDE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).